Somatic mutation profile of tumor specimen MP2PRT-PAPIUW-TMP1-A (aliquot MP2PRT-PAPIUW-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIUW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,304 days).
Specimen MP2PRT-PAPIUW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd7ee6e-a549-49d4-8a3a-970c1a181272.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIUW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIUW-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9db50b37-9397-41c8-a957-3bf0043454e8

The open-access MAF lists 133 somatic variants for this specimen: 91 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 37, Nonsense Mutation 9, Intron 4, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.7123G>A p.E2375K | Missense Mutation (SNP) | VAF 52/530 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs398122955, CM1311051, COSV58701225; ClinVar: pathogenic; called by muse, mutect2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 71/452 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.3791C>T p.S1264F | Missense Mutation (SNP) | VAF 49/596 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52469740; called by muse, mutect2
- C1orf94 | c.577G>A p.V193I (on ENST00000488417 / NM_001134734.2; = p.V3I on NM_032884.5) | Missense Mutation (SNP) | VAF 121/449 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs773093561; called by muse, mutect2, varscan2
- C8B | c.1489C>A p.Q497K | Missense Mutation (SNP) | VAF 113/474 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.72); catalogued as COSV64779620; called by muse, mutect2, varscan2
- CGN | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1292331764, COSV54970824; called by muse, mutect2
- CHD7 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 46/572 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs371930390; ClinVar: uncertain significance; called by muse, mutect2
- COL6A6 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62037312; called by muse, mutect2
- CUBN | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.66); catalogued as COSV100913064; called by muse, mutect2
- EEF1AKMT3 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 96/471 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.062); catalogued as rs751954455; called by muse, mutect2, varscan2
- GCK | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 21/419 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1431824236; called by muse, mutect2
- GIPC3 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 34/685 reads (5%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.742); catalogued as rs1022369946; called by muse, mutect2
- GRIA1 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 24/357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99597556; called by muse, mutect2
- HCN4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 60/751 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs1465495839, COSV99983874; called by muse, mutect2
- IFT74 | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 17/415 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV66286530; called by muse, mutect2
- KANSL1L | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 15/291 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV55995954; called by muse, mutect2
- MTHFD2L | c.987G>A p.M329I (on ENST00000395759 / NM_001144978.2; = p.M271I on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs1210326122; called by muse, mutect2, varscan2
- NLRP6 | c.2595G>C p.K865N | Missense Mutation (SNP) | VAF 43/530 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV100380935, COSV100381072; called by muse, mutect2
- OR51I1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99061844; called by muse, mutect2, varscan2
- PLPPR3 | c.1205C>T p.S402L (on ENST00000520876 / NM_001270366.2; = p.S430L on NM_024888.2) | Missense Mutation (SNP) | VAF 43/762 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs774892631; called by muse, mutect2
- PLXNB2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 82/516 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as rs771239742; called by muse, mutect2, varscan2
- PNMA3 | c.1214C>G p.S405* | Nonsense Mutation (SNP) | VAF 34/382 reads (9%) | catalogued as COSV64723077; called by muse, mutect2
- POLG | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 50/764 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1382145186, COSV51519850; called by muse, mutect2
- RAET1G | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 81/645 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.137); catalogued as rs766367536; called by muse, mutect2, varscan2
- RASGRP1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV60367198; called by muse, mutect2
- SCN3A | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 16/204 reads (8%) | catalogued as rs1553518052; called by muse, mutect2
- SLCO2B1 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 139/545 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111782322; called by muse, mutect2, varscan2
- SMS | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV65113687; called by muse, mutect2
- SVEP1 | c.2702C>G p.S901* | Nonsense Mutation (SNP) | VAF 16/396 reads (4%) | catalogued as COSV100237480; called by muse, mutect2
- TMC4 | c.441G>T p.W147C (on ENST00000617472 / NM_001145303.3; = p.W141C on NM_144686.4) | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as rs147493600, COSV55475120; called by muse, mutect2
- TRPM6 | c.4234C>T p.H1412Y | Missense Mutation (SNP) | VAF 75/418 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs765550122; called by muse, mutect2, varscan2
- TTC21A | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs199645072; called by muse, mutect2, varscan2
- WDR17 | c.3620C>T p.S1207F | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99707850; called by muse, mutect2, varscan2
- WRN | c.3175C>G p.Q1059E | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.078); catalogued as COSV53303752; called by muse, mutect2, varscan2
- ZIM3 | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV54147750; called by muse, mutect2
- ZNF626 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs1156259606; called by muse, mutect2
- ZNF724 | c.1472C>G p.S491* | Nonsense Mutation (SNP) | VAF 16/340 reads (5%) | catalogued as COSV69030202; called by muse, mutect2
- ADGB | c.1483C>G p.Q495E | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2
- ADGRD1 | c.1425G>C p.Q475H | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- ALS2 | c.3499G>C p.D1167H | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD63 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 28/652 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2
- ASB14 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1C | c.1613C>A p.T538K | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CTAGE1 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- DNAH11 | c.3868G>C p.E1290Q | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.031); called by muse, mutect2
- EYA1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2
- FER1L5 | c.1935G>C p.K645N (on ENST00000623019; = p.K650N on NM_001293083.2) | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2
- FER1L6 | c.4984C>T p.Q1662* | Nonsense Mutation (SNP) | VAF 30/412 reads (7%) | called by muse, mutect2
- FITM2 | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- FRMPD3 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FRY | c.8877G>C p.Q2959H | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- HACE1 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 11/340 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2
- HOXA11 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 19/389 reads (5%) | called by muse, mutect2
- IGKV3-20 | chr2:89142573 GA>C | Missense Mutation (DEL) | VAF 66/297 reads (22%) | called by pindel, varscan2*
- KLHL40 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 131/652 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- KMT2C | c.6496C>T p.P2166S | Missense Mutation (SNP) | VAF 42/622 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- LAMA1 | c.7262G>C p.G2421A | Missense Mutation (SNP) | VAF 43/686 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMLN | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- LONRF1 | c.735G>C p.L245F | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.029); called by muse, mutect2
- LONRF3 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 22/363 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.495); called by muse, mutect2
- LYSMD3 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 26/541 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2
- MASTL | c.2137C>G p.Q713E (on ENST00000375940 / NM_001372029.1; = p.Q712E on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2
- MEI4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MYOCD | c.2585C>A p.S862Y | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 15/444 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NIPA1 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 50/510 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.636); called by muse, mutect2
- NLRP11 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2
- NRXN3 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 22/592 reads (4%) | called by muse, mutect2
- OR6B1 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 19/518 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- PAX4 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.356); called by muse, mutect2
- PCDHGC4 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PKHD1L1 | c.7013A>C p.Q2338P | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2
- POLK | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- POM121L12 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- RGS22 | c.587_588insGGC p.L196_G197insA | In Frame Ins (INS) | VAF 36/158 reads (23%) | called by mutect2, pindel*, varscan2
- RHBDD3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 137/543 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RUFY3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SUPT3H | c.544G>A p.E182K (on ENST00000371460 / NM_181356.3; = p.E171K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- TAS2R39 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2
- TBL3 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- TES | c.1251G>C p.K417N | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX11 | c.656C>G p.S219* (on ENST00000344304; = p.S204* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- TF | c.802C>G p.H268D | Missense Mutation (SNP) | VAF 119/418 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULBP1 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 21/466 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- VGF | c.1821C>G p.I607M | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- VPS13A | c.2794G>C p.E932Q | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- YTHDF3 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB1 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB8B | c.989C>G p.S330* | Nonsense Mutation (SNP) | VAF 13/329 reads (4%) | called by muse, mutect2
- ZNF506 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- ZNF670 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2
- ABCB5 | c.2524C>T p.L842= (on ENST00000404938 / NM_001163941.2; = p.L397= on NM_178559.6) | Silent (SNP) | VAF 38/446 reads (9%) | catalogued as COSV51708911; called by muse, mutect2
- ADAMTS6 | c.999C>G p.L333= | Silent (SNP) | VAF 20/427 reads (5%) | catalogued as COSV101125083; called by muse, mutect2
- ASPH | c.1569T>C p.D523= | Silent (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- ATG16L1 | c.540G>C p.L180= | Silent (SNP) | VAF 40/442 reads (9%) | catalogued as COSV61464282; called by muse, mutect2
- CFAP70 | c.114T>C p.N38= | Silent (SNP) | VAF 87/359 reads (24%) | called by muse, mutect2, varscan2
- CIB2 | c.123C>T p.L41= | Silent (SNP) | VAF 24/343 reads (7%) | catalogued as rs780117405, COSV51947814; called by muse, mutect2
- CLASP2 | c.2739G>A p.L913= | Silent (SNP) | VAF 27/320 reads (8%) | catalogued as rs1353632246; called by muse, mutect2
- DCDC2B | c.1049G>A p.*350= | Silent (SNP) | VAF 17/337 reads (5%) | called by muse, mutect2
- DHX15 | c.2139G>A p.V713= | Silent (SNP) | VAF 15/397 reads (4%) | called by muse, mutect2
- DNAH3 | c.10608G>T p.L3536= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- DTWD1 | c.27C>G p.L9= | Silent (SNP) | VAF 26/268 reads (10%) | catalogued as COSV52072540; called by muse, mutect2
- EFR3B | c.1491C>G p.L497= | Silent (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- FGD2 | c.1452C>T p.C484= | Silent (SNP) | VAF 111/413 reads (27%) | catalogued as rs755349931; called by muse, mutect2, varscan2
- GPS1 | c.534C>G p.L178= | Silent (SNP) | VAF 35/511 reads (7%) | called by muse, mutect2
- GPS1 | c.1239C>A p.I413= | Silent (SNP) | VAF 18/437 reads (4%) | called by muse, mutect2
- GSC | c.141C>T p.S47= | Silent (SNP) | VAF 60/882 reads (7%) | called by muse, mutect2
- H2BC4 | c.33G>A p.P11= | Silent (SNP) | VAF 14/205 reads (7%) | catalogued as rs370298383; called by muse, mutect2
- IQCH | c.1662G>C p.L554= | Silent (SNP) | VAF 29/345 reads (8%) | called by muse, mutect2
- ISLR | c.816G>A p.Q272= | Silent (SNP) | VAF 55/689 reads (8%) | called by muse, mutect2
- KCNK10 | c.1206C>T p.A402= | Silent (SNP) | VAF 19/708 reads (3%) | called by muse, mutect2
- LGALS9C | c.1020C>T p.I340= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2, varscan2
- LRIF1 | c.1146G>A p.Q382= | Silent (SNP) | VAF 15/486 reads (3%) | called by muse, mutect2
- MAPK8IP2 | c.1251G>A p.P417= | Silent (SNP) | VAF 62/408 reads (15%) | called by muse, mutect2, varscan2
- MYO7A | c.2412G>A p.R804= | Silent (SNP) | VAF 49/710 reads (7%) | called by muse, mutect2
- OR5M8 | c.663C>T p.F221= | Silent (SNP) | VAF 74/384 reads (19%) | catalogued as rs771221040, COSV59115724; called by muse, mutect2, varscan2
- PCDH12 | c.1665C>G p.L555= | Silent (SNP) | VAF 51/589 reads (9%) | catalogued as COSV51519574; called by muse, mutect2
- PRR14L | c.6315C>G p.V2105= | Silent (SNP) | VAF 20/529 reads (4%) | called by muse, mutect2
- SPACA4 | c.69C>T p.C23= | Silent (SNP) | VAF 23/594 reads (4%) | catalogued as rs1393160788; called by muse, mutect2
- STXBP5 | c.1554C>T p.I518= | Silent (SNP) | VAF 61/330 reads (18%) | catalogued as rs779531913; called by muse, mutect2, varscan2
- TAF1C | c.501C>T p.L167= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as rs976268661; called by muse, mutect2, varscan2
- THBS2 | c.222C>T p.I74= | Silent (SNP) | VAF 21/623 reads (3%) | called by muse, mutect2
- TMEM39A | c.1272C>T p.L424= | Silent (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- TTN | c.84936C>G p.L28312= (on ENST00000591111; = p.L20888= on NM_003319.4) | Silent (SNP) | VAF 18/495 reads (4%) | called by muse, mutect2
- URB1 | c.4731C>T p.C1577= | Silent (SNP) | VAF 81/807 reads (10%) | called by muse, mutect2, varscan2
- ZBTB48 | c.207C>T p.F69= | Silent (SNP) | VAF 24/470 reads (5%) | catalogued as rs1258865272, COSV59841045; called by muse, mutect2
- ZNF165 | c.18G>A p.K6= | Silent (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- ZNF592 | c.2697C>G p.L899= | Silent (SNP) | VAF 20/382 reads (5%) | catalogued as rs1567077478, COSV100246167; called by muse, mutect2
- GMPPA | c.853+70C>T | Intron (SNP) | VAF 90/642 reads (14%) | catalogued as rs1297879170, COSV58007525; called by muse, varscan2
- IGKV3-15 | chr2:89085176 ins GGGGGGA | 3'Flank (INS) | VAF 44/312 reads (14%) | called by mutect2, pindel, varscan2
- KCNQ1 | c.1514+5968G>A | Intron (SNP) | VAF 17/438 reads (4%) | called by muse, mutect2
- SET | c.113-1174C>T | Intron (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- TCP10L3 | n.2719+994C>G | Intron (SNP) | VAF 16/410 reads (4%) | called by muse, mutect2
